Somatic mutation profile of tumor specimen TCGA-09-1670-01A (aliquot TCGA-09-1670-01A-01W-0633-09) from TCGA case TCGA-09-1670, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.9 years (21,147 days).
Specimen TCGA-09-1670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d38698be-1463-4db6-bb3a-f6f6bddb2906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-1670-10A (Blood Derived Normal), aliquot TCGA-09-1670-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b69bc84e-f625-4baf-a95f-dd53e4f7e809

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Splice Site 2, Nonsense Mutation 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 117/131 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.2626A>G p.K876E | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99710640; called by muse, mutect2
- ADCY2 | c.1787C>A p.A596E | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV57883500; called by muse, mutect2, varscan2
- ARID3B | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs1567127286, COSV60557773; called by muse, mutect2, varscan2
- BIRC6 | c.1973A>T p.H658L | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV70202424; called by muse, mutect2, varscan2
- DEFB125 | c.234A>G p.I78M | Missense Mutation (SNP) | VAF 62/529 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV66703430; called by muse, mutect2, varscan2
- DGKK | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV65708402; called by muse, mutect2, varscan2
- ERICH3 | c.3952G>C p.G1318R | Missense Mutation (SNP) | VAF 403/1195 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1401686560, COSV58600748, COSV58611638; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs79936844, COSV58559305; called by muse, mutect2, varscan2
- GABPA | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV61396895; called by muse, mutect2, varscan2
- GRIK2 | c.31C>G p.P11A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV59750877; called by muse, mutect2, varscan2
- IDH1 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV61630505; called by muse, mutect2, varscan2
- MTMR7 | c.1510T>A p.Y504N | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51668083; called by muse, mutect2, varscan2
- NEURL4 | c.4285C>T p.R1429W | Missense Mutation (SNP) | VAF 78/89 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59748539; called by muse, mutect2, varscan2
- NF1 | c.4747G>T p.E1583* (on ENST00000358273 / NM_001042492.3; = p.E1562* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 196/252 reads (78%) | catalogued as COSV62194721; called by muse, mutect2, varscan2
- OR2T6 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs182818153, COSV63215979; called by muse, mutect2, varscan2
- PIK3C2B | c.3788A>G p.Q1263R | Missense Mutation (SNP) | VAF 117/455 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV65812866; called by muse, mutect2, varscan2
- PPP1R3A | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 10/348 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV99493181, COSV99494112; called by muse, mutect2
- PTPRT | c.2312+1G>A p.X771_splice | Splice Site (SNP) | VAF 55/298 reads (18%) | catalogued as COSV61996904; called by muse, mutect2, varscan2
- SH2D2A | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 104/291 reads (36%) | catalogued as COSV63885068; called by muse, mutect2, varscan2
- SORCS1 | c.663T>G p.N221K | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV53883190; called by muse, mutect2, varscan2
- SPTBN1 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs759737447, COSV61690516; called by muse, mutect2, varscan2
- ZNF536 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194604006, COSV62823839, COSV62824796; called by muse, mutect2, varscan2
- ZNF627 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as rs773591634, COSV63142528; called by muse, mutect2, varscan2
- ELF3 | c.1033_1044del p.V345_R348del | In Frame Del (DEL) | VAF 32/91 reads (35%) | called by mutect2, pindel, varscan2
- FRG2C | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD6 | c.2445A>G p.L815= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as COSV58559289; called by muse, mutect2, varscan2
- CXCR1 | c.798C>T p.T266= | Silent (SNP) | VAF 65/286 reads (23%) | catalogued as COSV55282346; called by muse, mutect2, varscan2
- IGSF9B | c.2529C>T p.A843= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV58069875; called by muse, mutect2, varscan2
- SEMA5B | c.1822C>A p.R608= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV52102286, COSV99533536; called by muse, mutect2, varscan2
- TAC3 | c.292+127G>A | Intron (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
